Somatic mutation profile of tumor specimen TCGA-MP-A4TF-01A (aliquot TCGA-MP-A4TF-01A-11D-A25L-08) from TCGA case TCGA-MP-A4TF, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 58.6 years (21,387 days).
Specimen TCGA-MP-A4TF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd3ed839-5f10-4388-b488-3c45b6e12822.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MP-A4TF-10A (Blood Derived Normal), aliquot TCGA-MP-A4TF-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81a8beea-4350-46e8-a4b6-335af0ba55c3

The open-access MAF lists 451 somatic variants for this specimen: 340 protein-altering or splice-affecting, 99 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 289, Silent 99, Nonsense Mutation 26, Frame Shift Del 12, Splice Site 7, Intron 5, RNA 3, 3'UTR 2, 5'UTR 2, Splice Region 2, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B2M | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs1023835002, COSV62562840, COSV62562870, COSV62563658; ClinVar: likely pathogenic; called by mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 168/177 reads (95%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.746G>T p.R249M | Missense Mutation (SNP) | VAF 21/62 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs587782329, COSV52666526, COSV52668050, COSV52697169, COSV52713804; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.2859G>C p.K953N | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99771695; called by muse, mutect2
- ABCA13 | c.14273C>A p.A4758D | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV68951699; called by muse, mutect2
- ABCB5 | c.1700T>A p.L567Q (on ENST00000404938 / NM_001163941.2; = p.L122Q on NM_178559.6) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99327916, COSV99329706; called by muse, mutect2, varscan2
- ABCC11 | c.1949C>A p.S650Y | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV100751153, COSV62324618; called by muse, mutect2, varscan2
- AC013489.1 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as rs201101298; called by mutect2, varscan2
- ACTB | c.655G>T p.V219F | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV100079958; called by muse, mutect2, varscan2
- ADGRV1 | c.4652G>T p.G1551V | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101316528; called by muse, mutect2, varscan2
- AGAP3 | c.2096A>G p.N699S (on ENST00000622464; = p.N735S on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1458293020, COSV101257438; called by muse, mutect2, varscan2
- AGBL2 | c.1631G>T p.R544I | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV100102135; called by muse, mutect2, varscan2
- AGRN | c.1678G>A p.V560M | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs761396188, COSV101039092; called by muse, mutect2, varscan2
- AHCYL2 | c.1296-2A>C p.X432_splice | Splice Site (SNP) | VAF 5/94 reads (5%) | catalogued as COSV100273766; called by muse, mutect2
- AIFM3 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 18/69 reads (26%) | catalogued as COSV100105102; called by muse, mutect2, varscan2
- AJAP1 | c.362del p.P121Qfs*32 | Frame Shift Del (DEL) | VAF 4/16 reads (25%) | catalogued as COSV100981669; called by mutect2, varscan2
- ALAS2 | c.1193del p.G398Afs*35 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | catalogued as CM109571; called by mutect2, pindel, varscan2
- APEX2 | c.1254G>C p.M418I | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100238660; called by muse, mutect2, varscan2
- APOA5 | c.349C>A p.L117M | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV99911500; called by muse, mutect2, varscan2
- APOB | c.12131G>T p.R4044M | Missense Mutation (SNP) | VAF 22/516 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.803); catalogued as COSV99268170; called by muse, mutect2
- ARHGAP33 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99140084; called by muse, mutect2, varscan2
- ARHGAP5 | c.2518A>G p.I840V | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.254); catalogued as rs151030401; called by muse, mutect2, varscan2
- ARMC2 | c.220C>T p.L74F | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV99410969; called by muse, mutect2, varscan2
- ARMC4 | c.599C>G p.T200R | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV99519063; called by muse, mutect2, varscan2
- ARMCX1 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV100863246; called by muse, mutect2, varscan2
- ASXL3 | c.1693G>T p.V565L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV52462197, COSV99326644; called by muse, mutect2, varscan2
- BAHCC1 | c.5705C>T p.S1902L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as rs782788793, COSV100312081; called by muse, mutect2, varscan2
- BMS1 | c.2150G>T p.R717L | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs374900295, COSV100996827; called by muse, mutect2, varscan2
- BRCA1 | c.3929C>T p.T1310I | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs80357257, COSV100525126; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRSK1 | c.1181G>T p.R394L | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV100474672; called by muse, mutect2, varscan2
- C15orf39 | c.1951T>A p.F651I | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100641477; called by muse, mutect2, varscan2
- C1QL2 | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); catalogued as COSV99733367; called by muse, mutect2
- C1QTNF3 | c.653T>A p.V218D | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99180733; called by muse, mutect2
- C3orf20 | c.868T>C p.C290R | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867787481, COSV99514569; called by muse, mutect2, varscan2
- CABIN1 | c.1225G>T p.D409Y | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99574054; called by muse, mutect2, varscan2
- CACNA2D1 | c.2539G>T p.V847L (on ENST00000356253 / NM_001366867.1; = p.V835L on NM_000722.4) | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV100667357; called by muse, varscan2
- CACNG8 | c.431T>C p.V144A | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.676); catalogued as COSV99555179; called by muse, mutect2
- CADM3 | c.149G>A p.C50Y (on ENST00000368125 / NM_001127173.3; = p.C84Y on NM_021189.5) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100930413; called by muse, varscan2
- CADM3 | c.151C>T p.Q51* (on ENST00000368125 / NM_001127173.3; = p.Q85* on NM_021189.5) | Nonsense Mutation (SNP) | VAF 30/66 reads (45%) | catalogued as COSV100930414; called by muse, varscan2
- CALCR | c.1196A>T p.Q399L (on ENST00000649521 / NM_001164737.2; = p.Q383L on NM_001742.4) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100810872; called by muse, mutect2, varscan2
- CAPN10 | c.265C>A p.L89M | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as COSV99550549; called by muse, mutect2, varscan2
- CAPN6 | c.1112C>A p.S371* | Nonsense Mutation (SNP) | VAF 57/435 reads (13%) | catalogued as COSV100137103; called by muse, mutect2, varscan2
- CBY2 | c.279C>A p.N93K | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV100137845; called by muse, mutect2, varscan2
- CBY2 | c.280C>A p.R94S | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100137847; called by muse, mutect2, varscan2
- CCDC63 | c.1536G>T p.R512S | Missense Mutation (SNP) | VAF 70/118 reads (59%) | SIFT tolerated (0.43); PolyPhen benign (0.058); catalogued as COSV100370631; called by muse, mutect2, varscan2
- CCDC74B | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as rs1490115279, COSV100134753, COSV60102345; called by muse, mutect2, varscan2
- CCL1 | c.145T>C p.C49R | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56775603; called by muse, mutect2
- CD163L1 | c.3551T>A p.L1184Q | Missense Mutation (SNP) | VAF 37/236 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100550679; called by muse, mutect2, varscan2
- CD1B | c.406C>G p.L136V | Missense Mutation (SNP) | VAF 158/346 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV100939305; called by muse, mutect2, varscan2
- CD44 | c.1870G>T p.D624Y | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV99556016; called by muse, mutect2, varscan2
- CD93 | c.1276C>A p.Q426K | Missense Mutation (SNP) | VAF 70/203 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99849600; called by muse, mutect2, varscan2
- CD96 | c.1385C>A p.P462H (on ENST00000283285 / NM_198196.3; = p.P446H on NM_005816.5) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99343604; called by muse, mutect2, varscan2
- CDH10 | c.95C>A p.P32Q | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100053156; called by muse, mutect2, varscan2
- CELF4 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.852); catalogued as COSV100612023; called by muse, mutect2, varscan2
- CFAP161 | c.789C>A p.H263Q | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV99715625; called by muse, mutect2, varscan2
- CFAP161 | c.790T>G p.W264G | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99715627; called by muse, mutect2, varscan2
- CHCHD2 | c.35T>A p.M12K | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.042); catalogued as COSV101271061; called by muse, mutect2, varscan2
- CHML | c.1846A>T p.I616F | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV100087883; called by muse, mutect2, varscan2
- CHRNA7 | c.1162G>T p.G388C | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV60967908; called by muse, mutect2, varscan2
- CLCA2 | c.2825T>A p.L942* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as COSV100991745; called by muse, mutect2
- CLEC14A | c.944del p.P315Rfs*26 | Frame Shift Del (DEL) | VAF 23/191 reads (12%) | catalogued as COSV60563142; called by mutect2, pindel, varscan2
- CNGB1 | c.1917G>T p.W639C | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV51901922, COSV99211443; called by muse, mutect2, varscan2
- CNTNAP4 | c.1801G>T p.G601* | Nonsense Mutation (SNP) | VAF 33/146 reads (23%) | catalogued as COSV100273108, COSV56677521; called by muse, mutect2, varscan2
- COL11A1 | c.1414-1G>T p.X472_splice | Splice Site (SNP) | VAF 3/10 reads (30%) | catalogued as rs80127346; called by muse, mutect2
- COL4A1 | c.861C>A p.G287= | Splice Region (SNP) | VAF 34/142 reads (24%) | catalogued as COSV101011612; called by muse, mutect2, varscan2
- CORO7 | c.2060T>C p.I687T | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs768734194, COSV99228145; called by muse, mutect2, varscan2
- CPED1 | c.2475G>T p.W825C | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100121504; called by muse, mutect2, varscan2
- CPS1 | c.2802G>T p.K934N | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99244101; called by muse, mutect2, varscan2
- CPT1A | c.1184G>T p.R395L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99681618; called by muse, mutect2, varscan2
- CPZ | c.392C>G p.P131R (on ENST00000360986 / NM_001014447.3; = p.P120R on NM_003652.3) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.071); catalogued as rs766936569, COSV100249288; called by muse, mutect2, varscan2
- CRADD | c.366G>T p.Q122H | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as COSV100257850; called by muse, mutect2, varscan2
- CSMD1 | c.5735G>T p.G1912V (on ENST00000520002; = p.G1911V on NM_033225.6) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100153839; called by muse, mutect2
- CSMD3 | c.9568G>T p.V3190L (on ENST00000297405 / NM_001363185.1; = p.V3021L on NM_052900.3) | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.099); catalogued as COSV99848037; called by muse, mutect2, varscan2
- CTNND2 | c.386G>A p.R129K | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV100481153; called by muse, mutect2, varscan2
- CXorf65 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as rs963337813, COSV52147220; called by muse, mutect2
- CXorf66 | c.777C>A p.N259K | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV65168945; called by muse, mutect2
- CYLC1 | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100255515; called by muse, mutect2, varscan2
- CYP11B1 | c.514C>A p.L172M | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV99455718; called by muse, mutect2, varscan2
- DCN | c.937T>G p.C313G | Missense Mutation (SNP) | VAF 76/141 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99272795; called by muse, mutect2, varscan2
- DEPDC5 | c.487G>T p.V163L | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV99836604; called by muse, mutect2, varscan2
- DHX15 | c.1687G>T p.A563S | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.173); catalogued as COSV100391761; called by muse, mutect2, varscan2
- DIPK2B | c.478C>A p.L160I | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV100933492; called by muse, mutect2, varscan2
- DNAH9 | c.10744C>A p.L3582M | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99308223; called by muse, mutect2, varscan2
- DNAI2 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100210081; called by muse, mutect2
- DOCK4 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs752637866; called by muse, mutect2, varscan2
- DOCK5 | c.1000C>T p.H334Y | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs1489434380, COSV99377939; called by muse, varscan2
- DOCK7 | c.1013A>T p.Q338L | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV99226042; called by muse, mutect2, varscan2
- DVL3 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100493810; called by muse, mutect2
- DYSF | c.744G>C p.Q248H | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV99250484; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1660G>T p.D554Y | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100668869; called by muse, mutect2, varscan2
- EGR1 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99525613; called by muse, mutect2, varscan2
- EMP3 | c.200A>T p.Q67L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99507565; called by muse, mutect2, varscan2
- ENPP1 | c.1630A>G p.M544V | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100719651; called by muse, mutect2, varscan2
- ERBB4 | c.2546T>G p.V849G | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100727822; called by muse, mutect2, varscan2
- FAM131B | c.267G>T p.Q89H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68126383; called by mutect2, varscan2
- FAM237A | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV101405601; called by muse, mutect2, varscan2
- FAM47A | c.317A>C p.K106T | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.6); catalogued as COSV100650090; called by muse, mutect2
- FAM47C | c.1276C>T p.L426F | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.13); catalogued as COSV100792951; called by muse, mutect2, varscan2
- FAM83B | c.2735C>A p.P912H | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV100175037; called by muse, mutect2, varscan2
- FFAR1 | c.572T>G p.F191C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99323785; called by muse, mutect2, varscan2
- FLG | c.9850G>C p.G3284R | Missense Mutation (SNP) | VAF 96/955 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1162425050, COSV100912228; called by muse, mutect2, varscan2
- FLNC | c.872C>A p.T291N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.21); catalogued as COSV100368756; called by muse, mutect2, varscan2
- FLNC | c.6433C>A p.P2145T | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as COSV100368760; called by muse, mutect2, varscan2
- FMN2 | c.3013G>T p.G1005* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100147174, COSV60430473; called by muse, varscan2
- FSHR | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100438114; called by muse, mutect2
- FUT3 | c.683C>G p.P228R | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV99744983; called by muse, mutect2, varscan2
- GABRA4 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99974713; called by muse, mutect2, varscan2
- GABRG3 | c.84A>T p.E28D | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100409931; called by muse, mutect2, varscan2
- GFOD2 | c.620A>G p.Q207R | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV99263730; called by muse, mutect2, varscan2
- GGT5 | c.253A>T p.S85C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99571879; called by muse, mutect2, varscan2
- GHRH | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 95/264 reads (36%) | catalogued as rs377413593; called by muse, mutect2, varscan2
- GKN1 | c.413T>A p.I138N | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100933618, COSV65006608; called by muse, mutect2
- GMNN | c.344A>T p.K115M | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100017786; called by muse, mutect2, varscan2
- GPR65 | c.611G>T p.R204L | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99966166; called by muse, mutect2, varscan2
- GPRASP1 | c.2327G>T p.G776V | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV100851078, COSV100851080; called by muse, mutect2, varscan2
- GPRIN3 | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as COSV100311016; called by muse, mutect2, varscan2
- GRHL3 | c.1016C>T p.S339F (on ENST00000350501 / NM_198174.3; = p.S344F on NM_021180.3) | Missense Mutation (SNP) | VAF 92/315 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99359717; called by muse, mutect2, varscan2
- GRIN2B | c.4021G>T p.E1341* | Nonsense Mutation (SNP) | VAF 18/81 reads (22%) | catalogued as rs371762359, COSV101663191, COSV74206579; called by muse, mutect2, varscan2
- GRM5 | c.1171C>A p.H391N | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV100554574; called by muse, mutect2, varscan2
- GRPEL1 | c.48G>T p.L16F | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99380610; called by muse, mutect2, varscan2
- HDAC9 | c.1324C>G p.R442G | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV67766859, COSV67772252; called by muse, mutect2, varscan2
- HEPH | c.3294G>T p.M1098I (on ENST00000343002; = p.M831I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.119); catalogued as rs1362419671, COSV100294889, COSV100295750; called by muse, mutect2, varscan2
- HERC1 | c.3491C>T p.P1164L | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs531482851, COSV101496922; called by muse, mutect2, varscan2
- HERC2 | c.14465T>A p.F4822Y | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV99876778; called by muse, mutect2, varscan2
- HERC2 | c.11619G>A p.W3873* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV55317981, COSV99876779; called by muse, mutect2, varscan2
- HK3 | c.1946G>T p.R649L | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99459409; called by muse, mutect2, varscan2
- HLA-G | c.386C>A p.S129Y | Missense Mutation (SNP) | VAF 20/257 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV100827199; called by muse, mutect2
- HOXA7 | c.391A>C p.K131Q | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99636774; called by muse, mutect2
- HPS4 | c.1799G>A p.S600N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.29); catalogued as COSV100404717; called by muse, mutect2, varscan2
- HTR3B | c.1322T>A p.V441E | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV99492313; called by muse, mutect2
- HTR5A | c.1064G>T p.R355M | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV99839997; called by muse, mutect2, varscan2
- HYDIN | c.766A>G p.M256V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs746779266, COSV99865370; called by muse, mutect2, varscan2
- IGHV1-2 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs782739184; called by muse, mutect2, varscan2
- IGSF1 | c.2689G>A p.G897R | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100812341, COSV63840149; called by muse, mutect2, varscan2
- IGSF6 | c.410C>A p.T137N | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99193665; called by muse, mutect2, varscan2
- INSRR | c.928C>A p.R310S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.555); catalogued as COSV100948106; called by muse, mutect2, varscan2
- INTS6 | c.1054G>T p.V352L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as COSV100247271; called by muse, mutect2, varscan2
- ITPR2 | c.4688T>G p.F1563C | Missense Mutation (SNP) | VAF 28/526 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as rs1201576803, COSV101190173; called by muse, mutect2
- KCNH4 | c.1611C>G p.D537E | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV99237938; called by muse, mutect2
- KCNT1 | c.3373G>T p.E1125* (on ENST00000488444; = p.E1151* on NM_020822.3) | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV99706715; called by muse, varscan2
- KIAA1210 | c.2186G>T p.C729F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV68175554; called by muse, mutect2, varscan2
- KLHL21 | c.1615G>T p.A539S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0.015); catalogued as COSV100887299; called by muse, mutect2, varscan2
- KMT2D | c.12956G>T p.R4319I | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.648); catalogued as COSV99982894; called by muse, mutect2, varscan2
- KNTC1 | c.4731G>T p.L1577F | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as COSV100338816; called by muse, mutect2, varscan2
- KRT72 | c.1066G>T p.E356* | Nonsense Mutation (SNP) | VAF 66/120 reads (55%) | catalogued as COSV99537498; called by muse, mutect2, varscan2
- LAMA1 | c.7447C>G p.L2483V | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.695); catalogued as COSV101057765; called by muse, mutect2, varscan2
- LARP4 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 33/65 reads (51%) | catalogued as COSV99529698; called by muse, mutect2, varscan2
- LCT | c.3682G>T p.D1228Y | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99930482; called by muse, mutect2
- LHFPL5 | c.51C>A p.N17K | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs1159620695, COSV100799030; called by muse, mutect2, varscan2
- LILRA2 | c.1359G>T p.M453I (on ENST00000391738 / NM_001130917.3; = p.M436I on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV99252728; called by muse, mutect2, varscan2
- LLCFC1 | c.439C>A p.L147I (on ENST00000458732; = p.L116I on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as COSV100787305; called by muse, mutect2, varscan2
- LRFN1 | c.1088G>T p.R363M | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99952723; called by muse, mutect2, varscan2
- LRIT2 | c.1579G>C p.V527L | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV100259391; called by muse, mutect2, varscan2
- LRP1B | c.12394G>T p.G4132* | Nonsense Mutation (SNP) | VAF 8/82 reads (10%) | catalogued as COSV67201068; called by muse, mutect2
- LRRC7 | c.2156G>C p.S719T (on ENST00000651989 / NM_001370785.2; = p.S686T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV50540396, COSV99229915; called by muse, mutect2, varscan2
- LRRC8B | c.940G>T p.V314F | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as COSV100446703; called by muse, mutect2, varscan2
- LRRN4 | c.1006G>C p.D336H | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV101125527; called by muse, mutect2, varscan2
- LSP1 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100289573, COSV61137503; called by muse, mutect2, varscan2
- LTK | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs766333097, COSV99541186; called by muse, mutect2, varscan2
- LTN1 | c.3831C>A p.S1277R | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as COSV100798231; called by muse, mutect2, varscan2
- LURAP1L | c.393G>T p.M131I | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV100070923; called by muse, mutect2, varscan2
- LZTR1 | c.2066C>G p.S689C | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV99302315; called by muse, mutect2, varscan2
- MAGEC2 | c.652G>T p.G218C | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99909946, COSV99909951; called by muse, mutect2, varscan2
- MAGEC3 | c.219G>T p.Q73H | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV100026140; called by muse, mutect2, varscan2
- MAPT | c.69G>T p.R23S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV52244319, COSV99291354; called by muse, mutect2, varscan2
- MARCHF4 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.156); catalogued as COSV99814822; called by muse, mutect2
- MARF1 | c.3763G>T p.D1255Y | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100706383; called by muse, mutect2, varscan2
- MCC | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 74/277 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as rs140863211; called by muse, mutect2, varscan2
- MED12 | c.3602C>A p.S1201Y | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.547); catalogued as COSV100375141; called by muse, mutect2, varscan2
- MMS22L | c.2040G>A p.R680= | Splice Region (SNP) | VAF 27/52 reads (52%) | catalogued as COSV99247770; called by muse, mutect2, varscan2
- MOG | c.117C>A p.H39Q | Missense Mutation (SNP) | VAF 138/318 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV100973143; called by muse, mutect2, varscan2
- MPHOSPH6 | c.483A>T p.*161Yext*28 | Nonstop Mutation (SNP) | VAF 36/99 reads (36%) | catalogued as COSV99259369; called by muse, mutect2, varscan2
- MTBP | c.1528T>G p.F510V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as COSV100012590; called by muse, mutect2, varscan2
- MTMR3 | c.1532G>C p.C511S | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as COSV100071381; called by muse, mutect2, varscan2
- MYH4 | c.4876C>G p.L1626V | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV99702265; called by muse, mutect2, varscan2
- MYH8 | c.168C>A p.S56R | Missense Mutation (SNP) | VAF 77/226 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV101238805; called by muse, mutect2, varscan2
- MYLK | c.1948C>A p.P650T | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100659647; called by muse, mutect2, varscan2
- MYO7B | c.3042G>T p.W1014C | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as COSV67353366; called by muse, varscan2
- MYO7B | c.3091G>T p.A1031S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.034); catalogued as COSV101268393, COSV67352021; called by muse, varscan2
- NALCN | c.784G>T p.G262C | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99217811; called by muse, mutect2, varscan2
- NCKAP5 | c.1356C>A p.C452* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as COSV100494455; called by muse, mutect2, varscan2
- NCKAP5L | c.3617C>T p.P1206L | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.116); catalogued as rs550998532, COSV100259243; called by muse, mutect2, varscan2
- NDE1 | c.13G>T p.G5* | Nonsense Mutation (SNP) | VAF 14/160 reads (9%) | catalogued as COSV100707346, COSV61270085; called by muse, mutect2
- NEK5 | c.1426C>A p.Q476K | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV100839305; called by muse, mutect2, varscan2
- NELL1 | c.2089C>G p.Q697E | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as COSV100125327, COSV54270575; called by muse, mutect2, varscan2
- NIN | c.3167G>A p.G1056E | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55392544; called by muse, mutect2, varscan2
- NLGN1 | c.1369C>A p.L457M | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.379); catalogued as COSV100850213; called by muse, mutect2, varscan2
- NLGN4X | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99320231, COSV99323981; called by muse, mutect2, varscan2
- NLRP10 | c.1159G>T p.A387S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.171); catalogued as COSV100149984; called by muse, mutect2
- NME8 | c.790C>A p.P264T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99553863; called by muse, mutect2, varscan2
- NOTCH4 | c.1561C>A p.P521T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs138825503; called by muse, mutect2, varscan2
- NRXN1 | c.2620T>A p.F874I | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV100456920; called by muse, mutect2, varscan2
- NSMAF | c.955C>A p.L319I | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.868); catalogued as COSV99233485; called by muse, mutect2, varscan2
- NTRK3 | c.2222G>T p.S741I (on ENST00000360948 / NM_001012338.2; = p.S727I on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100712688; called by muse, mutect2, varscan2
- NTRK3 | c.1091T>C p.L364P | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.53); catalogued as COSV100448102; called by muse, mutect2
- OFD1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as CM130030, COSV100407158; called by muse, mutect2, varscan2
- OLFM3 | c.1097C>A p.A366E (on ENST00000338858 / NM_001288821.1; = p.A346E on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100130107; called by muse, mutect2, varscan2
- OR11G2 | c.967C>A p.L323I | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV100640053; called by muse, mutect2, varscan2
- OR2B11 | c.552G>C p.E184D | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV100276669, COSV59510124; called by muse, mutect2, varscan2
- OR2B6 | c.258C>A p.C86* | Nonsense Mutation (SNP) | VAF 26/105 reads (25%) | catalogued as COSV55128632, COSV99773855; called by muse, mutect2, varscan2
- OR2M3 | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 114/286 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.516); catalogued as COSV71759000, COSV71759041; called by muse, mutect2, varscan2
- OR2V2 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV100080243; called by muse, mutect2, varscan2
- OR4C46 | c.176T>A p.L59H | Missense Mutation (SNP) | VAF 99/307 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.132); catalogued as rs755794716, COSV100061006; called by muse, mutect2, varscan2
- OR4D10 | c.536G>T p.C179F | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101597033; called by muse, mutect2, varscan2
- OR51A2 | c.919A>G p.K307E | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.434); catalogued as COSV100985094; called by muse, mutect2, varscan2
- OR51B6 | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs747661195, COSV100972054; called by muse, mutect2
- OR56A1 | c.825C>G p.I275M | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100360559, COSV57362463; called by muse, mutect2, varscan2
- OR5A1 | c.517G>T p.G173* | Nonsense Mutation (SNP) | VAF 115/333 reads (35%) | catalogued as COSV100118475; called by muse, mutect2, varscan2
- OR5AK2 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as COSV100476165; called by muse, mutect2
- OR5F1 | c.177G>T p.M59I | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99558934; called by muse, mutect2, varscan2
- OR6B1 | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV68769846; called by muse, mutect2, varscan2
- OR6S1 | c.244A>C p.K82Q | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100289535; called by muse, mutect2, varscan2
- OSMR | c.871A>G p.K291E | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV99953737; called by muse, mutect2, varscan2
- PAPPA2 | c.1814C>A p.T605K | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100867178; called by muse, mutect2, varscan2
- PARD3B | c.3533C>T p.P1178L (on ENST00000406610 / NM_001302769.2; = p.P1109L on NM_057177.7) | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV100595307; called by muse, mutect2, varscan2
- PCDH11X | c.2809C>T p.R937* | Nonsense Mutation (SNP) | VAF 31/237 reads (13%) | catalogued as COSV53478900; called by muse, mutect2, varscan2
- PCDHA2 | c.1134C>A p.D378E | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100974150; called by muse, mutect2, varscan2
- PCDHA5 | c.517C>A p.P173T | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.24); catalogued as COSV100972554; called by muse, mutect2, varscan2
- PCDHB5 | c.1262C>T p.T421I | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV50686048; called by muse, mutect2, varscan2
- PCDHB7 | c.2027C>G p.A676G | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.649); catalogued as COSV99175175, COSV99177408; called by muse, mutect2, varscan2
- PCDHGA6 | c.1807T>A p.W603R | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV99547221; called by muse, mutect2, varscan2
- PGBD1 | c.967T>A p.W323R | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.019); catalogued as COSV99460944; called by muse, mutect2, varscan2
- PGK1 | c.116+1G>T p.X39_splice | Splice Site (SNP) | VAF 9/66 reads (14%) | catalogued as COSV100965376; called by muse, mutect2, varscan2
- PGLYRP3 | c.58A>T p.T20S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV99319958; called by muse, mutect2, varscan2
- PLCB1 | c.3473C>A p.P1158H | Missense Mutation (SNP) | VAF 69/253 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV62054802, COSV62058563; called by muse, mutect2, varscan2
- PLCL2 | c.3139G>A p.G1047S (on ENST00000615277 / NM_001144382.2; = p.G921S on NM_015184.5) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV101197007; called by muse, mutect2, varscan2
- PLPPR4 | c.1417C>A p.P473T | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV100926941; called by muse, mutect2, varscan2
- PLXNB3 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.186); catalogued as COSV100737944; called by muse, mutect2, varscan2
- PNMA5 | c.1153G>T p.G385C | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV100721716; called by muse, mutect2, varscan2
- PNMA5 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 12/154 reads (8%) | catalogued as COSV100721717, COSV62625766; called by muse, mutect2
- POMGNT1 | c.891C>A p.N297K | Missense Mutation (SNP) | VAF 3/30 reads (10%) | PolyPhen benign (0.192); catalogued as COSV100915814; called by muse, mutect2
- PPARGC1A | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV104393777, COSV99338688; called by muse, mutect2, varscan2
- PPP1R18 | c.419G>C p.R140T | Missense Mutation (SNP) | VAF 18/249 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); catalogued as COSV99223930; called by muse, mutect2
- PPP1R3A | c.2171A>G p.K724R | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV99494330; called by muse, mutect2
- PRDM7 | c.1167G>T p.M389I | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV100371369; called by muse, mutect2, varscan2
- PRKDC | c.9837C>G p.S3279R | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV100042929; called by muse, mutect2
- PRPF40B | c.1064A>G p.E355G (on ENST00000380281; = p.E349G on NM_012272.3) | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.767); catalogued as COSV99980168; called by muse, mutect2, varscan2
- PSG4 | c.259C>G p.Q87E | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV54941298; called by muse, mutect2, varscan2
- PTCD1 | c.139A>T p.S47C | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV99462675; called by muse, mutect2, varscan2
- PTK7 | c.476C>T p.T159I | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as COSV100030657; called by muse, mutect2, varscan2
- PTPN4 | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99751441; called by muse, mutect2, varscan2
- RACK1 | c.777G>A p.W259* | Nonsense Mutation (SNP) | VAF 16/135 reads (12%) | catalogued as COSV100163524; called by muse, mutect2, varscan2
- RANBP3 | c.1453G>A p.V485M (on ENST00000340578 / NM_007322.3; = p.V480M on NM_003624.3) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs750943746, COSV50383254, COSV99222511; called by muse, mutect2, varscan2
- RHBDL3 | c.220A>G p.K74E | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs775316192, COSV99283970; called by muse, mutect2, varscan2
- RIT2 | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as COSV100451864; called by muse, mutect2, varscan2
- RNASE11 | c.467C>A p.T156K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV100250629; called by muse, mutect2, varscan2
- RNF144A | c.194G>C p.C65S | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100306139; called by muse, mutect2, varscan2
- RPA1 | c.935C>G p.S312W | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV54607855; called by muse, mutect2, varscan2
- RTTN | c.80G>T p.C27F | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.054); catalogued as CM128056, COSV99733837; called by muse, mutect2, varscan2
- RYR3 | c.11601G>T p.L3867F (on ENST00000389232; = p.L3868F on NM_001036.6) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101212693; called by mutect2, varscan2
- S1PR1 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV59512501; called by muse, mutect2, varscan2
- SASS6 | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV54926779; called by muse, mutect2, varscan2
- SAXO1 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.92); catalogued as COSV101000208; called by muse, mutect2, varscan2
- SERPINI2 | c.1037C>A p.A346D | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99248449; called by muse, mutect2, varscan2
- SETDB1 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99645893; called by muse, mutect2, varscan2
- SH3BP2 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as COSV100697048; called by muse, mutect2, varscan2
- SLC38A7 | c.511C>A p.P171T | Missense Mutation (SNP) | VAF 71/119 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as COSV99543947; called by muse, mutect2, varscan2
- SLC6A5 | c.904T>A p.F302I | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV100117169; called by muse, mutect2, varscan2
- SLC7A2 | c.1811G>T p.R604I (on ENST00000494857 / NM_001370338.1; = p.R643I on NM_003046.6) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV99135982; called by muse, mutect2, varscan2
- SLC9A2 | c.2137C>A p.R713S | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.066); catalogued as rs1327032925, COSV52135089, COSV99296855; called by muse, mutect2, varscan2
- SLCO4C1 | c.1470-1G>T p.X490_splice | Splice Site (SNP) | VAF 18/85 reads (21%) | catalogued as COSV60517200, COSV60520622; called by muse, mutect2, varscan2
- SLIT3 | c.1829+1G>A p.X610_splice | Splice Site (SNP) | VAF 14/78 reads (18%) | catalogued as COSV100270000; called by muse, mutect2, varscan2
- SMARCA1 | c.2429C>T p.T810I | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); catalogued as rs1200970940, COSV100946727; called by muse, mutect2, varscan2
- SMC1A | c.1927G>C p.G643R | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100447683; called by muse, mutect2, varscan2
- SORCS1 | c.3034G>T p.A1012S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV99550448; called by muse, mutect2
- SORL1 | c.6461G>T p.G2154V | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99495526; called by muse, mutect2, varscan2
- SP100 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs752616413, COSV99894243; called by mutect2, varscan2
- SP140 | c.1031C>A p.S344Y | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.395); catalogued as COSV100614106; called by muse, mutect2, varscan2
- SPANXN3 | c.350C>G p.S117* | Nonsense Mutation (SNP) | VAF 16/112 reads (14%) | catalogued as COSV100980884, COSV65139992; called by muse, mutect2, varscan2
- SPAST | c.1365C>A p.H455Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100188756, COSV59515866; called by muse, mutect2, varscan2
- SPNS1 | c.1561G>T p.V521L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.59); catalogued as COSV100209300; called by muse, mutect2, varscan2
- SPTBN5 | c.9081G>T p.M3027I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.059); catalogued as COSV100312211; called by muse, mutect2, varscan2
- SPTBN5 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770147789, COSV100312214; called by muse, mutect2, varscan2
- STAB2 | c.3464G>A p.G1155D | Missense Mutation (SNP) | VAF 71/103 reads (69%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.875); catalogued as rs141142013, COSV101186326; called by muse, mutect2, varscan2
- SYT10 | c.623G>A p.R208K | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs1374809585, COSV99952009, COSV99952187; called by muse, mutect2
- SYTL2 | c.226A>G p.M76V | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs377321313, COSV100315008; called by muse, mutect2, varscan2
- TAGAP | c.496C>A p.P166T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100487653, COSV57851658; called by muse, mutect2, varscan2
- TEX13A | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100782072; called by muse, mutect2, varscan2
- THSD4 | c.1558G>T p.G520C | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99967159; called by muse, mutect2, varscan2
- TIMD4 | c.97G>C p.G33R | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99192902; called by muse, mutect2, varscan2
- TLE4 | c.453C>A p.H151Q | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV99513205; called by muse, mutect2, varscan2
- TM6SF1 | c.107T>A p.V36E | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as COSV99362893; called by muse, mutect2, varscan2
- TNN | c.588C>A p.D196E | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV99513075; called by muse, mutect2
- TNN | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 85/162 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); catalogued as rs142549967; called by muse, mutect2, varscan2
- TPP2 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV65753894; called by muse, mutect2, varscan2
- TRHR | c.680C>A p.P227H | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.179); catalogued as COSV100305120, COSV61236448; called by muse, mutect2, varscan2
- TRIM32 | c.1816G>A p.G606R | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100530377, COSV57761193; called by muse, mutect2, varscan2
- TRMT5 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV99712361; called by muse, mutect2, varscan2
- TRPC7 | c.1429G>C p.G477R | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV100726022, COSV61462282; called by muse, mutect2, varscan2
- TRPS1 | c.1068G>T p.Q356H (on ENST00000220888 / NM_001330599.2; = p.Q369H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.359); catalogued as COSV55226924, COSV99634535; called by muse, mutect2, varscan2
- TRRAP | c.9085A>T p.N3029Y (on ENST00000359863 / NM_001244580.1; = p.N3000Y on NM_003496.3) | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as COSV100723005; called by muse, mutect2, varscan2
- TSPYL2 | c.1336A>T p.T446S | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.283); catalogued as COSV100966367; called by muse, mutect2, varscan2
- TSPYL6 | c.302C>A p.A101D | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.304); catalogued as COSV100336894; called by muse, mutect2
- UACA | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100537787, COSV59853039; called by muse, mutect2, varscan2
- UBA7 | c.1407G>T p.M469I | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100339870; called by muse, mutect2, varscan2
- UBE2A | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as COSV100660543; called by muse, mutect2
- USH2A | c.8200G>A p.V2734M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397518035, COSV100242885; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VEGFD | c.204G>T p.R68S | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs747254028, COSV52910337, COSV99938544; called by muse, mutect2
- WDR47 | c.523T>G p.F175V | Missense Mutation (SNP) | VAF 55/262 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100728456; called by muse, mutect2, varscan2
- XIRP2 | c.4403G>C p.R1468T (on ENST00000628543; = p.R1643T on NM_152381.6) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.17); catalogued as COSV99747568; called by muse, mutect2, varscan2
- XRN1 | c.2930G>C p.W977S | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99378943; called by muse, mutect2, varscan2
- ZBTB21 | c.1315G>T p.D439Y | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100177369; called by muse, mutect2, varscan2
- ZCCHC12 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.181); catalogued as COSV100038679; called by muse, mutect2
- ZFAND2B | c.271C>G p.Q91E | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV54698458, COSV99202511; called by muse, mutect2, varscan2
- ZFYVE16 | c.2262G>T p.M754I | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100566655; called by muse, mutect2, varscan2
- ZNF106 | c.1744C>T p.Q582* | Nonsense Mutation (SNP) | VAF 18/140 reads (13%) | catalogued as COSV55516020; called by muse, mutect2, varscan2
- ZNF107 | c.2116A>G p.N706D | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as COSV100788530; called by muse, mutect2, varscan2
- ZNF219 | c.1989G>T p.L663F | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100070721; called by muse, mutect2, varscan2
- ZNF345 | c.136C>A p.P46T | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV100080453; called by muse, mutect2
- ZNF479 | c.25G>T p.G9* | Nonsense Mutation (SNP) | VAF 44/144 reads (31%) | catalogued as COSV58636062; called by muse, mutect2, varscan2
- ZNF536 | c.157C>G p.R53G | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.414); catalogued as COSV100835934, COSV62817581; called by muse, mutect2, varscan2
- ZNF536 | c.158G>C p.R53P | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1404382104, COSV100835935; called by muse, mutect2, varscan2
- ZNF556 | c.414G>C p.K138N | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.154); catalogued as COSV100298926, COSV56914420; called by muse, mutect2, varscan2
- ZNF607 | c.1502G>T p.G501V | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100777961; called by muse, mutect2, varscan2
- ZNF628 | c.1636G>T p.A546S | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.147); catalogued as COSV99220297; called by muse, mutect2, varscan2
- ZNF677 | c.1043A>C p.K348T | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1243681764, COSV100448181; called by muse, mutect2, varscan2
- ZNF711 | c.118C>G p.H40D | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.95); catalogued as COSV52159192, COSV99341633; called by muse, mutect2, varscan2
- ZNF804B | c.191A>G p.Y64C | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60817105; called by muse, mutect2, varscan2
- ZNF862 | c.2758G>T p.D920Y | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV99783835; called by muse, mutect2, varscan2
- ARHGAP10 | c.1830del p.V611Wfs*37 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | called by mutect2, varscan2
- CACNA2D1 | c.1179_1184del p.Y394_D395del | In Frame Del (DEL) | VAF 5/42 reads (12%) | called by mutect2, pindel, varscan2
- CEP70 | c.1418_1419del p.F473Sfs*5 | Frame Shift Del (DEL) | VAF 149/522 reads (29%) | called by mutect2, pindel, varscan2
- DPYSL4 | c.1388C>A p.P463Q | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FCGBP | c.283_285delinsTT p.K95Lfs*4 | Frame Shift Del (DEL) | VAF 31/94 reads (33%) | called by pindel, varscan2*
- FXR1 | c.990_990+3del p.X330_splice | Splice Site (DEL) | VAF 11/60 reads (18%) | called by mutect2, pindel
- IGKV1D-16 | c.281C>A p.T94N | Missense Mutation (SNP) | VAF 108/274 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- IGKV5-2 | c.42G>T p.W14C | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.18117_18118del p.P6040Sfs*22 | Frame Shift Del (DEL) | VAF 46/162 reads (28%) | called by pindel, varscan2
- PAK5 | c.553del p.V185* | Frame Shift Del (DEL) | VAF 65/214 reads (30%) | called by mutect2, pindel, varscan2
- PKNOX2 | c.814_815del p.Q272Gfs*2 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by pindel, varscan2
- PRAMEF20 | c.165G>T p.M55I | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- PRAMEF20 | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- PSIP1 | c.1341_1344del p.Q447Hfs*21 | Frame Shift Del (DEL) | VAF 23/128 reads (18%) | called by mutect2, pindel, varscan2
- SEMA4C | c.1571G>T p.S524I | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.233); called by muse, mutect2
- SLC10A3 | c.894C>A p.F298L | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SNRNP200 | c.4971del p.A1658Pfs*4 | Frame Shift Del (DEL) | VAF 9/98 reads (9%) | called by mutect2, pindel
- SYNRG | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UGT2A1 | c.200del p.P67Hfs*3 | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | called by mutect2, pindel, varscan2
- WDR83 | c.574+4_574+9del p.X192_splice | Splice Site (DEL) | VAF 5/12 reads (42%) | called by mutect2, varscan2
- ZRSR2 | c.50dup p.Y18Vfs*37 | Frame Shift Ins (INS) | VAF 6/56 reads (11%) | called by mutect2, varscan2
- AASDH | c.1560A>G p.L520= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV99221909; called by muse, mutect2, varscan2
- ACSM1 | c.114A>G p.P38= | Silent (SNP) | VAF 44/164 reads (27%) | catalogued as COSV99533453; called by muse, mutect2, varscan2
- ADAMTS5 | c.2697G>A p.T899= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as rs143254778; called by muse, mutect2, varscan2
- AKAP3 | c.330C>G p.G110= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as COSV99962638; called by muse, mutect2, varscan2
- ALPK2 | c.1470A>T p.S490= | Silent (SNP) | VAF 61/145 reads (42%) | catalogued as COSV100864819; called by muse, mutect2, varscan2
- ANKRD30A | c.192C>T p.I64= (on ENST00000611781; = p.I8= on NM_052997.2) | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs761265123, COSV100654460; called by muse, mutect2, varscan2
- APBB1IP | c.589C>A p.R197= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV100770919; called by muse, mutect2, varscan2
- APCDD1L | c.1380C>G p.P460= | Silent (SNP) | VAF 48/154 reads (31%) | catalogued as COSV100954096; called by muse, mutect2, varscan2
- ARSK | c.387G>T p.L129= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV101187586; called by muse, mutect2, varscan2
- BANP | c.723C>T p.I241= (on ENST00000286122; = p.I210= on NM_017869.4) | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99622366; called by muse, mutect2
- C17orf64 | c.588G>T p.L196= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV99293651; called by muse, mutect2, varscan2
- CADM3 | c.150C>T p.C50= (on ENST00000368125 / NM_001127173.3; = p.C84= on NM_021189.5) | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as rs1262642836, COSV63683592; called by muse, varscan2
- CAVIN1 | c.972C>T p.H324= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as rs1421562805, COSV100824606; called by muse, mutect2, varscan2
- CD163 | c.2697T>A p.P899= | Silent (SNP) | VAF 31/132 reads (23%) | catalogued as COSV100776145; called by muse, mutect2, varscan2
- CD40LG | c.594C>A p.P198= | Silent (SNP) | VAF 45/392 reads (11%) | catalogued as CD050483, COSV101033448, COSV101033572, COSV65699141; called by muse, mutect2, varscan2
- CDHR1 | c.1656C>T p.D552= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as COSV100259390; called by muse, mutect2, varscan2
- CEACAM8 | c.144G>T p.G48= | Silent (SNP) | VAF 41/200 reads (21%) | catalogued as COSV54990079, COSV99747869; called by muse, mutect2, varscan2
- CFAP161 | c.684G>C p.L228= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV99715623; called by muse, mutect2, varscan2
- CFAP92 | c.495G>C p.S165= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV99414954; called by muse, mutect2, varscan2
- CNGB3 | c.234C>A p.S78= | Silent (SNP) | VAF 105/360 reads (29%) | catalogued as COSV100183091; called by muse, mutect2, varscan2
- CPXCR1 | c.621C>A p.P207= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99342365; called by muse, mutect2, varscan2
- CRACR2A | c.1179A>C p.G393= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as COSV99365522; called by muse, mutect2
- CYP27C1 | c.252C>T p.Y84= | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as COSV100080055; called by muse, mutect2, varscan2
- CYP4F8 | c.27G>A p.L9= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV100358250; called by muse, mutect2, varscan2
- DCAF4L2 | c.405G>T p.L135= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as COSV100150767; called by muse, mutect2, varscan2
- DCSTAMP | c.303T>A p.A101= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV99886973; called by muse, mutect2, varscan2
- DHRS3 | c.735G>T p.T245= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs150030750, COSV100879690; called by muse, mutect2, varscan2
- DRD5 | c.201G>T p.R67= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as rs1478394029, COSV100432036, COSV58579606; called by muse, mutect2, varscan2
- EDARADD | c.441G>A p.G147= (on ENST00000334232 / NM_145861.4; = p.G137= on NM_080738.4) | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV100513138; called by muse, mutect2, varscan2
- ERN2 | c.1746G>T p.R582= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV99892398; called by muse, mutect2, varscan2
- FCGR2B | c.291C>T p.P97= | Silent (SNP) | VAF 62/125 reads (50%) | catalogued as rs1232100059, COSV99375403; called by muse, mutect2, varscan2
- FGD1 | c.2841C>T p.A947= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as rs1015067517, COSV100911262; called by muse, mutect2
- FLNC | c.5082G>A p.V1694= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV100368758; called by muse, mutect2, varscan2
- GABRB3 | c.831C>A p.A277= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV100161894; called by muse, mutect2, varscan2
- GDPD2 | c.954G>T p.G318= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs1461945278, COSV100978709; called by muse, mutect2, varscan2
- GPR139 | c.558C>T p.I186= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV58504528; called by muse, mutect2
- GPR83 | c.537C>A p.P179= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs767295508, COSV99703826; called by muse, mutect2, varscan2
- GZMB | c.384G>A p.R128= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs1443107372, COSV99362541; called by muse, mutect2, varscan2
- HLA-G | c.387C>G p.S129= | Silent (SNP) | VAF 20/258 reads (8%) | catalogued as rs1238539821, COSV100827201; called by muse, mutect2
- IGF1R | c.666G>T p.R222= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99151460, COSV99163106; called by muse, mutect2, varscan2
- IL16 | c.945C>A p.P315= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100268162; called by muse, mutect2, varscan2
- INSRR | c.3354C>A p.A1118= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV100948104; called by muse, mutect2, varscan2
- KBTBD2 | c.711G>C p.L237= | Silent (SNP) | VAF 8/89 reads (9%) | catalogued as COSV100406600; called by muse, mutect2
- KLF1 | c.981C>A p.T327= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV99322507; called by muse, mutect2, varscan2
- LAT2 | c.306C>T p.S102= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV99305957; called by muse, mutect2
- LRRC4 | c.276C>T p.A92= | Silent (SNP) | VAF 17/137 reads (12%) | catalogued as rs1563094808, COSV99974877; called by muse, mutect2, varscan2
- LUZP4 | c.453C>T p.G151= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV100904886; called by muse, mutect2, varscan2
- MAGEC3 | c.564G>T p.V188= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as COSV71610181; called by muse, mutect2
- MAGEL2 | c.3279G>T p.L1093= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV100046215; called by muse, mutect2, varscan2
- MAP7D3 | c.1020G>T p.V340= | Silent (SNP) | VAF 24/191 reads (13%) | catalogued as COSV100286714; called by muse, mutect2, varscan2
- MDC1 | c.2418G>T p.G806= | Silent (SNP) | VAF 21/263 reads (8%) | catalogued as COSV100903092; called by muse, mutect2
- MGAM | c.5460C>T p.V1820= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV101527713; called by muse, mutect2, varscan2
- MID1 | c.1500C>G p.S500= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as rs1481616335, COSV100452731; called by muse, mutect2, varscan2
- MRPL18 | c.219C>T p.P73= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs1271639117, COSV100365011, COSV100365080; called by muse, mutect2, varscan2
- MUC17 | c.390C>A p.P130= | Silent (SNP) | VAF 24/129 reads (19%) | catalogued as COSV100075091; called by muse, mutect2, varscan2
- MYLK3 | c.1782G>C p.G594= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV101189222; called by muse, mutect2, varscan2
- NLGN4X | c.168G>T p.R56= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as COSV52015343; called by muse, mutect2, varscan2
- NLRP7 | c.2163G>A p.R721= (on ENST00000340844 / NM_206828.3; = p.R693= on NM_139176.3) | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV60177064; called by muse, mutect2, varscan2
- OBSCN | c.9876G>T p.T3292= | Silent (SNP) | VAF 53/109 reads (49%) | catalogued as COSV99484428; called by muse, mutect2, varscan2
- OBSL1 | c.3201G>T p.S1067= | Silent (SNP) | VAF 24/238 reads (10%) | catalogued as COSV99217523; called by muse, mutect2
- OLFM1 | c.156G>T p.L52= (on ENST00000371793 / NM_001282611.2; = p.L34= on NM_006334.4) | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99424324; called by muse, mutect2, varscan2
- OR52B4 | c.36A>T p.T12= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV101281612; called by muse, mutect2, varscan2
- OTOGL | c.5124A>T p.I1708= (on ENST00000547103; = p.I1699= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV100087932; called by muse, mutect2, varscan2
- PABPC4 | c.1683A>T p.A561= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as COSV100865521; called by muse, mutect2, varscan2
- PCDHB1 | c.1593G>T p.V531= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV100128422; called by muse, mutect2, varscan2
- PCDHB10 | c.453A>T p.A151= | Silent (SNP) | VAF 53/195 reads (27%) | catalogued as COSV99505047; called by muse, mutect2, varscan2
- PDZRN3 | c.2973G>T p.R991= | Silent (SNP) | VAF 59/206 reads (29%) | catalogued as COSV55204328, COSV99732153; called by muse, mutect2, varscan2
- PKDREJ | c.4089T>C p.S1363= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV99479553; called by muse, mutect2, varscan2
- PMFBP1 | c.1443G>T p.L481= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV99401532; called by muse, mutect2, varscan2
- PPM1L | c.831G>T p.V277= | Silent (SNP) | VAF 42/97 reads (43%) | catalogued as COSV99862230; called by muse, mutect2, varscan2
- PSMB11 | c.297C>A p.A99= | Silent (SNP) | VAF 35/111 reads (32%) | catalogued as COSV101273641; called by muse, mutect2, varscan2
- PXDN | c.3180C>A p.G1060= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99414969; called by muse, mutect2
- RBM26 | c.1434A>G p.K478= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV99936643; called by muse, mutect2, varscan2
- REG3A | c.411C>A p.P137= | Silent (SNP) | VAF 12/165 reads (7%) | catalogued as COSV100532923; called by muse, mutect2
- RNASE9 | c.168C>A p.P56= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as COSV100141370, COSV58880940; called by muse, mutect2, varscan2
- RPH3A | c.102C>A p.S34= (on ENST00000389385 / NM_001143854.2; = p.S30= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/84 reads (55%) | catalogued as COSV101231894; called by muse, mutect2, varscan2
- RYR1 | c.5895T>C p.Y1965= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs1394957449, COSV100617039; called by muse, mutect2, varscan2
- SEC23IP | c.189G>A p.E63= | Silent (SNP) | VAF 12/135 reads (9%) | catalogued as COSV100957112; called by muse, mutect2
- SECISBP2 | c.789A>T p.A263= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100368893; called by muse, mutect2, varscan2
- SERPINA6 | c.846G>C p.R282= | Silent (SNP) | VAF 57/134 reads (43%) | catalogued as COSV100448485; called by muse, mutect2, varscan2
- SETBP1 | c.3819G>A p.T1273= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs764859310, COSV99955039; called by muse, mutect2, varscan2
- SLC10A2 | c.357C>A p.V119= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV55360319, COSV99808284; called by muse, mutect2, varscan2
- SNRNP200 | c.2793A>G p.R931= | Silent (SNP) | VAF 8/99 reads (8%) | catalogued as COSV100108062; called by muse, mutect2
- SPTLC3 | c.822C>T p.H274= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV100983301; called by muse, mutect2, varscan2
- SRRM4 | c.531C>A p.P177= | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as COSV57416659; called by muse, mutect2, varscan2
- SYAP1 | c.636A>T p.S212= | Silent (SNP) | VAF 33/133 reads (25%) | catalogued as COSV101204975; called by muse, mutect2, varscan2
- SYCE1 | c.823C>A p.R275= (on ENST00000343131 / NM_001143764.3; = p.R239= on NM_130784.3) | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100385747, COSV58215856; called by muse, mutect2, varscan2
- SYN3 | c.939C>T p.N313= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV100250003; called by muse, mutect2, varscan2
- TBC1D32 | c.2053C>T p.L685= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs906771040, COSV99251328; called by muse, mutect2, varscan2
- TFPT | c.27C>T p.T9= | Silent (SNP) | VAF 49/225 reads (22%) | catalogued as COSV100320128; called by muse, mutect2, varscan2
- TMEM19 | c.939G>T p.V313= | Silent (SNP) | VAF 124/240 reads (52%) | catalogued as COSV99877163; called by muse, mutect2, varscan2
- TMEM9B | c.456T>C p.F152= | Silent (SNP) | VAF 6/89 reads (7%) | catalogued as COSV100483605; called by muse, mutect2
- TMLHE | c.933C>T p.H311= | Silent (SNP) | VAF 23/171 reads (13%) | catalogued as COSV100545103; called by muse, mutect2, varscan2
- TTN | c.23859G>T p.L7953= (on ENST00000591111; = p.L7026= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV100630508, COSV100635843; called by muse, mutect2, varscan2
- TULP1 | c.7C>T p.L3= | Silent (SNP) | VAF 37/79 reads (47%) | catalogued as rs1269509447, COSV57692351; called by muse, mutect2, varscan2
- UNC45B | c.1995G>A p.K665= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV52100387; called by muse, mutect2, varscan2
- USP34 | c.7887G>A p.Q2629= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV101277231; called by muse, mutect2, varscan2
- VSIG8 | c.24C>T p.H8= | Silent (SNP) | VAF 16/160 reads (10%) | catalogued as rs1434595877, COSV100928842; called by muse, mutect2
- VWA3A | c.2283G>T p.G761= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100241325; called by muse, mutect2
- AQR | c.472-1054G>T | Intron (SNP) | VAF 43/186 reads (23%) | catalogued as rs747073151; called by muse, mutect2, varscan2
- CHCHD2P9 | n.30C>G | RNA (SNP) | VAF 32/86 reads (37%) | called by muse, mutect2, varscan2
- CHCHD2P9 | n.31C>A | RNA (SNP) | VAF 32/86 reads (37%) | called by muse, mutect2, varscan2
- CLDN16 | c.-21C>A | 5'UTR (SNP) | VAF 42/122 reads (34%) | catalogued as COSV53227045, COSV99290386; called by muse, mutect2, varscan2
- MAGEA5 | n.204C>A | RNA (SNP) | VAF 11/132 reads (8%) | called by muse, mutect2
- NAA20 | c.-1G>T | 5'UTR (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100131841; called by muse, mutect2
- PSG5 | c.431-2802G>T | Intron (SNP) | VAF 78/207 reads (38%) | catalogued as rs762744154, COSV100743168; called by muse, mutect2, varscan2
- SLIT2 | c.1463-624C>T | Intron (SNP) | VAF 10/63 reads (16%) | catalogued as rs747310658, COSV99887377; called by muse, mutect2, varscan2
- TANGO2 | c.-39-3584G>T | Intron (SNP) | VAF 22/95 reads (23%) | catalogued as COSV100530159; called by muse, mutect2, varscan2
- TNKS | c.2643+6188C>T | Intron (SNP) | VAF 19/45 reads (42%) | catalogued as rs548843321, COSV100127905; called by muse, mutect2, varscan2
- TRIM8 | c.*725C>T | 3'UTR (SNP) | VAF 13/54 reads (24%) | catalogued as COSV100193460; called by muse, mutect2, varscan2
- VRK2 | c.*71T>G | 3'UTR (SNP) | VAF 7/45 reads (16%) | catalogued as COSV99287932; called by muse, mutect2, varscan2
